Somatic mutation profile of tumor specimen TCGA-PK-A5HA-01A (aliquot TCGA-PK-A5HA-01A-11D-A29I-10) from TCGA case TCGA-PK-A5HA, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 63.9 years (23,345 days).
Specimen TCGA-PK-A5HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 458dfe9a-67e4-42b6-b446-b8780402e055.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PK-A5HA-10A (Blood Derived Normal), aliquot TCGA-PK-A5HA-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08a1da94-89d4-439e-a006-0cb91a1c7587

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 10, Nonsense Mutation 3, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJUBA | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52985750, COSV52986912; called by muse, mutect2, varscan2
- ARHGAP44 | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 46/62 reads (74%) | catalogued as COSV99310343; called by muse, mutect2, varscan2
- C8orf34 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs775847499, COSV57398948; called by muse, mutect2, varscan2
- EPB41L3 | c.2779C>A p.Q927K | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV59447196; called by muse, varscan2
- GAL3ST2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs143165919; called by muse, mutect2, varscan2
- ITLN1 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs1022786885, COSV58276265; called by muse, mutect2, varscan2
- IZUMO2 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220785294; called by muse, mutect2
- KMT2D | c.14600A>G p.Y4867C | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs923959182; called by muse, mutect2, varscan2
- MUC16 | c.34166C>T p.S11389L | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV67500193; called by muse, mutect2
- MUC6 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 78/114 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.412); catalogued as rs372014357; called by muse, mutect2, varscan2
- MYEF2 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs751571503; called by muse, mutect2, varscan2
- NLN | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101114100, COSV101114314; called by muse, mutect2, varscan2
- PAPPA2 | c.1527G>C p.L509F | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62776803; called by muse, mutect2, varscan2
- PCDHB12 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.459); catalogued as rs1554287140, COSV53396545; called by muse, mutect2, varscan2
- SLC7A6 | c.1228T>G p.Y410D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50450793; called by muse, mutect2, varscan2
- SORBS2 | c.2873C>T p.S958L (on ENST00000284776 / NM_021069.5; = p.S524L on NM_003603.6) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs781609153; called by muse, mutect2, varscan2
- SOX13 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs1484853955; called by muse, mutect2, varscan2
- ALOX5 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP44 | c.2429A>C p.E810A | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ASXL3 | c.1730C>A p.S577Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CDCA2 | c.2141G>T p.C714F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.06); called by muse, mutect2
- CDCP1 | c.1765A>T p.T589S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DMAP1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- DNAH10 | c.12277C>T p.Q4093* (on ENST00000409039; = p.Q4032* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 91/220 reads (41%) | called by muse, mutect2, varscan2
- DSG1 | c.2780T>A p.I927N | Missense Mutation (SNP) | VAF 96/150 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FNDC1 | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- FSTL4 | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2
- FSTL4 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2
- HIVEP1 | c.5490G>C p.L1830F | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HS3ST2 | c.453C>G p.D151E | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- HSP90AB1 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- IPP | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2
- KCNH1 | c.1723G>C p.V575L (on ENST00000271751 / NM_172362.3; = p.V548L on NM_002238.4) | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.102); called by muse, mutect2
- KIRREL1 | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC61 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- LRRTM4 | c.1256A>T p.H419L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NUP210 | c.4288G>C p.D1430H | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M2 | c.221T>A p.I74N | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- RIMBP2 | c.2156del p.G719Afs*8 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- SLAMF6 | c.647-1G>T p.X216_splice | Splice Site (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- TMEM155 | c.260C>G p.P87R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- VNN3 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFYVE28 | c.1676G>T p.C559F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ZNF585B | c.2287G>T p.V763F | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ABCC8 | c.528G>C p.V176= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV56853501; called by muse, mutect2, varscan2
- AOC3 | c.2136C>T p.D712= | Silent (SNP) | VAF 71/96 reads (74%) | catalogued as rs769070236; called by muse, mutect2, varscan2
- CFAP58 | c.2613G>A p.T871= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs370337063; called by muse, mutect2, varscan2
- IL1RAP | c.105C>T p.I35= | Silent (SNP) | VAF 27/157 reads (17%) | called by muse, mutect2, varscan2
- OR5J2 | c.27C>T p.V9= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1350963845, COSV56620638; called by muse, mutect2, varscan2
- PTGFR | c.141C>A p.A47= | Silent (SNP) | VAF 56/78 reads (72%) | called by muse, mutect2, varscan2
- PTPRM | c.1410C>T p.S470= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- SLC2A6 | c.1122C>T p.G374= | Silent (SNP) | VAF 60/133 reads (45%) | catalogued as COSV52470888; called by muse, mutect2, varscan2
- TUT7 | c.213T>A p.A71= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as rs1235842228; called by muse, mutect2, varscan2
- ZFP36 | c.909C>T p.P303= (on ENST00000594442; = p.P297= on NM_003407.5) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs752975772, COSV99953799; called by muse, mutect2, varscan2
- GCNT2 | c.926-34679G>A | Intron (SNP) | VAF 29/183 reads (16%) | catalogued as rs755228157, CM024256, COSV99399186; called by muse, mutect2, varscan2
